Somatic mutation profile of tumor specimen ALCH-B0CO-TTP1-A (aliquot ALCH-B0CO-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.2 years (22,350 days).
Specimen ALCH-B0CO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b49a5b7-8f09-46e4-8f8b-d8c38c38eb40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CO-NB1-A (Blood Derived Normal), aliquot ALCH-B0CO-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13f83312-a644-402a-97ce-4446e234840f

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 5, Intron 3, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 182/880 reads (21%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ACKR2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs866153853; called by muse, varscan2
- ANKRD36C | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 32/513 reads (6%) | catalogued as rs76474100; called by muse, mutect2
- C8B | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 92/737 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186622094, COSV64777141; called by muse, mutect2, varscan2
- CMC2 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs986430937; called by muse, mutect2, varscan2
- DISP1 | c.2891A>G p.N964S | Missense Mutation (SNP) | VAF 50/509 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1450970962; called by muse, mutect2, varscan2
- DNAH1 | c.4315G>T p.A1439S | Missense Mutation (SNP) | VAF 47/581 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.387); catalogued as rs768831672; called by muse, mutect2
- GRAMD4 | c.1616C>T p.T539M | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs954698303; called by muse, mutect2
- H2BC21 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 86/1059 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2
- IGHV3-23 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 61/1178 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs537381127; called by muse, mutect2
- ITGA8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 51/521 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs748005596, COSV65229891; called by muse, mutect2
- KCNA4 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV104407327, COSV60255648; called by muse, mutect2, varscan2
- LGALS16 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 41/374 reads (11%) | catalogued as rs748468958; called by muse, mutect2, varscan2
- LILRB4 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs755568653, COSV54407497; called by muse, mutect2, varscan2
- MARCHF4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367784136, COSV99814011; called by muse, mutect2
- PNISR | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65079594, COSV65080687; called by muse, mutect2
- USP44 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 56/655 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1215568656; called by muse, mutect2
- ZBTB18 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 52/1074 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV62396300; called by muse, mutect2
- ZNF451 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62600509; called by muse, mutect2, varscan2
- ALG1L | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 72/779 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- APCDD1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- ARHGAP5 | c.3085G>C p.D1029H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); called by muse, mutect2
- BRD8 | c.2183A>G p.Y728C (on ENST00000254900 / NM_139199.2; = p.Y801C on NM_006696.4) | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRINP2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP295 | c.6442G>C p.D2148H | Missense Mutation (SNP) | VAF 52/635 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- DCAF12L2 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 52/508 reads (10%) | called by muse, mutect2, varscan2
- ERICH1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2
- FMN2 | c.139_180del p.K47_E60del | In Frame Del (DEL) | VAF 21/307 reads (7%) | called by mutect2, pindel
- GRHL2 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 84/1214 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.342); called by muse, mutect2
- HSPH1 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- LINGO4 | c.1305C>A p.C435* | Nonsense Mutation (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- NOTCH4 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- POLA2 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 48/593 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2
- PRUNE2 | c.5828C>A p.S1943Y | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SATB2 | c.1252A>G p.M418V | Missense Mutation (SNP) | VAF 100/1204 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMYD2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 84/580 reads (14%) | called by muse, mutect2, varscan2
- SUPV3L1 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 77/681 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFR2 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 102/1120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM26 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 58/610 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- UGT2B7 | c.221T>G p.I74S | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- WDR7 | c.1685C>G p.P562R | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZXDB | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); called by muse, mutect2
- C12orf50 | c.180C>T p.S60= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV100072466, COSV53895812; called by muse, mutect2
- CLASP2 | c.117G>T p.S39= | Silent (SNP) | VAF 30/633 reads (5%) | catalogued as rs761762860; called by muse, mutect2
- FABP7 | c.165C>G p.L55= | Silent (SNP) | VAF 36/378 reads (10%) | catalogued as COSV100737923; called by muse, mutect2
- GDPD2 | c.51C>T p.C17= | Silent (SNP) | VAF 35/353 reads (10%) | catalogued as rs745867534; called by muse, mutect2, varscan2
- GPRC5B | c.642C>T p.T214= | Silent (SNP) | VAF 100/1254 reads (8%) | catalogued as rs766338650; called by muse, mutect2
- MDGA2 | c.2367C>T p.L789= (on ENST00000399232 / NM_001113498.2; = p.L491= on NM_182830.4) | Silent (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- MME | c.1275G>A p.R425= | Silent (SNP) | VAF 34/271 reads (13%) | called by muse, mutect2, varscan2
- OR7G2 | c.288A>C p.T96= | Silent (SNP) | VAF 93/808 reads (12%) | called by muse, varscan2
- PARP10 | c.87C>T p.L29= | Silent (SNP) | VAF 22/674 reads (3%) | called by muse, mutect2
- PSEN2 | c.624C>T p.V208= | Silent (SNP) | VAF 74/923 reads (8%) | called by muse, mutect2
- DLG2 | c.205-65783G>A | Intron (SNP) | VAF 28/470 reads (6%) | catalogued as rs45482499, COSV54634359, COSV99717820; called by muse, mutect2
- PDCL | c.355-140C>T | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- SKA2P1 | n.98G>A | RNA (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- TMEM170A | c.133+225G>C | Intron (SNP) | VAF 26/305 reads (9%) | called by muse, mutect2
